Somatic mutation profile of tumor specimen TCGA-UY-A78O-01A (aliquot TCGA-UY-A78O-01A-12D-A339-08) from TCGA case TCGA-UY-A78O, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 74.6 years (27,234 days).
Specimen TCGA-UY-A78O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba8820b4-3d25-439c-a376-a6b4b7d4550f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UY-A78O-10A (Blood Derived Normal), aliquot TCGA-UY-A78O-10A-01D-A339-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76bf9f5d-607c-4b00-9921-88ee1665e773

The open-access MAF lists 202 somatic variants for this specimen: 148 protein-altering or splice-affecting, 50 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 136, Silent 50, Nonsense Mutation 3, Frame Shift Del 3, Intron 2, Frame Shift Ins 2, Splice Site 2, RNA 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 94/201 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50461395, COSV50462411; called by muse, mutect2, varscan2
- TP53 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52666332, COSV52700326, COSV52746468; called by muse, mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACIN1 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.108); catalogued as COSV52972689; called by muse, mutect2, varscan2
- ACTN2 | c.220C>A p.L74M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100856687; called by muse, mutect2
- AFF2 | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 72/284 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV60653317; called by muse, mutect2, varscan2
- AL592490.1 | c.679C>G p.R227G | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV101308178, COSV69424337; called by muse, mutect2, varscan2
- ALDH1A1 | c.327G>C p.M109I | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV52788857; called by muse, mutect2, varscan2
- ANKRD52 | c.981G>C p.Q327H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as COSV99921177; called by mutect2, varscan2
- ANO10 | c.731T>C p.V244A | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.449); catalogued as COSV52727972; called by muse, mutect2
- ARHGAP31 | c.1374C>A p.N458K | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs1330888590, COSV51788604; called by muse, mutect2, varscan2
- ARID4A | c.1080T>G p.D360E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV62161782; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.149); catalogued as COSV63436936, COSV63438036; called by muse, varscan2
- BRINP1 | c.2254C>T p.Q752* | Nonsense Mutation (SNP) | VAF 75/140 reads (54%) | catalogued as COSV56309934, COSV99774984; called by muse, mutect2, varscan2
- BZW1 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV63349371; called by muse, mutect2, varscan2
- C3 | c.4152G>A p.M1384I | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV55567972; called by muse, mutect2, varscan2
- CDC25A | c.566G>C p.R189T | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as COSV56769596, COSV56769671; called by muse, mutect2, varscan2
- CFAP91 | c.1047G>C p.K349N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV56338755; called by muse, mutect2, varscan2
- CHD4 | c.2315C>G p.S772C (on ENST00000357008 / NM_001363606.2; = p.S785C on NM_001273.5) | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58893828; called by muse, mutect2, varscan2
- CLEC1B | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.758); catalogued as rs935242723, COSV53724634, COSV53725234; called by muse, mutect2, varscan2
- COL1A1 | c.3508C>A p.R1170S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.988); catalogued as COSV56802115; called by muse, mutect2, varscan2
- COPA | c.1828G>C p.E610Q | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.088); catalogued as rs1423249244, COSV54097318; called by muse, mutect2
- CSMD2 | c.3808G>A p.E1270K | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs932600876, COSV53874885, COSV99588242; called by muse, mutect2, varscan2
- CTSC | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV57055862; called by muse, mutect2, varscan2
- CYP26B1 | c.465G>C p.E155D | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs752223643, COSV50010601; called by muse, mutect2, varscan2
- CYP26B1 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.697); catalogued as COSV50010610, COSV50011475; called by muse, mutect2, varscan2
- DDX39A | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV54390335; called by muse, mutect2, varscan2
- DENND1B | c.1555C>G p.L519V | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.279); catalogued as rs975871201; called by muse, mutect2
- DIAPH2 | c.2452_2453insT p.T818Ifs*5 | Frame Shift Ins (INS) | VAF 7/40 reads (18%) | catalogued as COSV61258905; called by mutect2, pindel, varscan2
- DNAH10 | c.13463G>A p.R4488Q (on ENST00000409039; = p.R4427Q on NM_207437.3) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as rs770503988, COSV53018416; called by muse, mutect2, varscan2
- DNAH11 | c.3894G>T p.Q1298H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV60937455; called by muse, mutect2, varscan2
- DNAH7 | c.1436T>C p.V479A | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV56750206; called by muse, mutect2, varscan2
- DNAI4 | c.1843G>T p.D615Y | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64020580, COSV64021843; called by muse, mutect2, varscan2
- ELF3 | c.892C>G p.R298G | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV62837022; called by muse, mutect2, varscan2
- ENOX1 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV54885810; called by mutect2, varscan2
- EXOSC5 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.08); catalogued as rs1471491159, COSV55370497, COSV55372247; called by muse, mutect2, varscan2
- FAM135B | c.74G>T p.R25I | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50524859, COSV50537129, COSV99356718; called by muse, mutect2
- FAM161A | c.1435G>C p.D479H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56764096; called by mutect2, varscan2
- FANCI | c.1167G>C p.L389F | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55522230; called by muse, mutect2
- FBN1 | c.6671C>A p.T2224N | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57308202; called by muse, mutect2, varscan2
- FIBCD1 | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as rs749270628, COSV99446916; called by muse, varscan2
- FRMPD4 | c.1940G>C p.R647T | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV66210870; called by muse, mutect2
- FZR1 | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as COSV58050057; called by muse, mutect2, varscan2
- G2E3 | c.1772C>G p.S591C | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52838287, COSV99249710; called by muse, mutect2, varscan2
- G6PD | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV63702164; called by muse, mutect2
- GLP1R | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs1189829779, COSV100952612, COSV64714124; called by muse, mutect2, varscan2
- GLT6D1 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs764884818, COSV65626919; called by muse, mutect2, varscan2
- GLTP | c.54C>G p.I18M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV59172349; called by muse, mutect2, varscan2
- GNPDA1 | c.834G>T p.E278D | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV60942090; called by muse, mutect2, varscan2
- GOLGA6L22 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs769611486; called by muse, mutect2, varscan2
- HNRNPA3 | c.235G>C p.G79R | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66820608; called by muse, mutect2, varscan2
- IGSF1 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 68/100 reads (68%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV63835834; called by muse, mutect2, varscan2
- IMPA2 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.458); catalogued as rs370481001, COSV99302695; called by mutect2, varscan2
- INSR | c.2719C>G p.L907V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs780429736, COSV100251870; called by muse, mutect2
- IRF2BP2 | c.1587C>G p.F529L | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1288000907, COSV64014496, COSV64014555; called by muse, mutect2
- ITGA4 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99275582; called by muse, mutect2, varscan2
- ITGA4 | c.1610C>G p.S537C | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as COSV51997483; called by muse, mutect2, varscan2
- JAK3 | c.3343G>A p.E1115K | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV71685379; called by muse, mutect2, varscan2
- KCTD8 | c.762G>C p.E254D | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.751); catalogued as COSV63595586; called by muse, mutect2
- KLK13 | c.588G>C p.K196N | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.424); catalogued as rs1335423055, COSV50066801; called by muse, mutect2
- LAMP2 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs200934351, COSV52351225; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- LRRC43 | c.1253C>G p.S418W | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV60287844, COSV60291038; called by muse, mutect2, varscan2
- LSM14A | c.1066C>G p.P356A | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV70884606; called by muse, mutect2, varscan2
- LYPD6 | c.221C>T p.T74I | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV61938424; called by muse, mutect2, varscan2
- LYST | c.5225C>T p.S1742L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.169); catalogued as COSV67702781; called by muse, mutect2, varscan2
- MAG | c.1514G>A p.G505E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.088); catalogued as COSV62698747; called by muse, mutect2, varscan2
- MAGI2 | c.3072G>C p.Q1024H | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV62631447; called by muse, mutect2
- MAPRE1 | c.705del p.N235Kfs*9 | Frame Shift Del (DEL) | VAF 30/282 reads (11%) | catalogued as COSV65032431; called by mutect2, pindel, varscan2
- MAS1 | c.869G>C p.R290T | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV53120445; called by muse, mutect2, varscan2
- MATR3 | c.856C>G p.P286A | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV63075424; called by muse, mutect2, varscan2
- MAU2 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99448516; called by muse, mutect2, varscan2
- MEOX1 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV59355135; called by muse, mutect2, varscan2
- MRPL50 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV66405950; called by muse, mutect2, varscan2
- MUC16 | c.36913C>T p.R12305C | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.556); catalogued as rs367821186; called by muse, mutect2, varscan2
- MYH15 | c.5113G>C p.E1705Q | Missense Mutation (SNP) | VAF 63/219 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV56303734; called by muse, mutect2, varscan2
- MYO9A | c.7045G>A p.E2349K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV61847051; called by muse, mutect2, varscan2
- NAA60 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs1184401308, COSV100692766; called by muse, mutect2
- NAV3 | c.3785C>T p.S1262F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV57059358, COSV57076543; called by muse, mutect2, varscan2
- NEB | c.10210G>T p.V3404F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV50805956, COSV99424858; called by muse, mutect2, varscan2
- NEPRO | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1209446128, COSV55605694, COSV99868383; called by muse, mutect2, varscan2
- NFATC2 | c.2518G>A p.G840S | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV65352925; called by muse, mutect2, varscan2
- NLGN1 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.133); catalogued as COSV64322416; called by muse, mutect2, varscan2
- NOX4 | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.214); catalogued as rs779238483, COSV54446031; called by mutect2, varscan2
- NOX5 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs562414382, COSV52984303; called by muse, mutect2, varscan2
- OR10G7 | c.198C>A p.F66L | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs548869259, COSV100389862, COSV57868478; called by muse, mutect2, varscan2
- OR4S2 | c.442G>T p.V148L | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV56745483; called by muse, mutect2, varscan2
- PALM | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.386); catalogued as rs760993265, COSV52766374; called by muse, mutect2, varscan2
- PCIF1 | c.549T>A p.N183K | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65026020; called by muse, mutect2, varscan2
- PCSK1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV60733480; called by muse, mutect2, varscan2
- PHF3 | c.2672C>G p.S891* | Nonsense Mutation (SNP) | VAF 22/73 reads (30%) | catalogued as COSV100013123; called by muse, mutect2, varscan2
- PIBF1 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58319746; called by muse, mutect2, varscan2
- PLXNA4 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs199571283, COSV58102572; called by muse, mutect2, varscan2
- PRKD2 | c.1505C>T p.T502I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV52184326; called by muse, mutect2, varscan2
- PRPF4B | c.2558G>C p.R853T | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61783160; called by muse, mutect2
- PRRT2 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs989894169, COSV54881036; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAMP3 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.153); catalogued as rs756936620, COSV54244718; called by muse, mutect2
- RBMXL1 | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV53097919; called by muse, mutect2, varscan2
- REST | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs1468725438, COSV58359163; called by muse, mutect2, varscan2
- REXO2 | c.646A>C p.K216Q | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as COSV56276339; called by muse, mutect2, varscan2
- RHOA | c.58T>G p.C20G | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV69041533; called by muse, mutect2, varscan2
- RNF157 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.254); catalogued as COSV53941522; called by muse, mutect2, varscan2
- ROBO2 | c.1648C>G p.L550V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV59894049; called by muse, mutect2, varscan2
- ROR1 | c.2025C>G p.I675M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV64283531; called by muse, mutect2, varscan2
- RPRD2 | c.2265G>C p.K755N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV64818492; called by muse, mutect2, varscan2
- RPS6KA1 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.273); catalogued as rs1469778897, COSV64809510; called by muse, mutect2, varscan2
- SAMD9L | c.1765C>T p.R589* | Nonsense Mutation (SNP) | VAF 26/112 reads (23%) | catalogued as rs763831653, COSV59083491; called by muse, mutect2, varscan2
- SLC39A6 | c.1878A>T p.L626F | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV52367626; called by muse, mutect2, varscan2
- SLC6A7 | c.859-2A>T p.X287_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | catalogued as rs752731637, COSV57941733; called by muse, mutect2
- SLCO1B3 | c.1898G>T p.R633I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV53931474; called by muse, mutect2, varscan2
- SPHKAP | c.2426C>T p.T809M | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs200506306; called by muse, mutect2, varscan2
- SRRM2 | c.5557C>T p.R1853C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs747392349, COSV57067241; called by muse, mutect2, varscan2
- STARD4 | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV56967130; called by muse, mutect2, varscan2
- STEAP2 | c.423G>C p.L141F | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV55288711; called by muse, mutect2, varscan2
- TACC2 | c.8671G>A p.E2891K (on ENST00000334433; = p.E969K on NM_006997.4) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53275977; called by muse, mutect2, varscan2
- TEAD1 | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV57560689, COSV57563771; called by muse, mutect2, varscan2
- TLCD3A | c.409-1G>C p.X137_splice | Splice Site (SNP) | VAF 15/45 reads (33%) | catalogued as COSV56744715; called by muse, mutect2, varscan2
- TLN2 | c.5032G>A p.E1678K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs1458131072, COSV60885011; called by muse, mutect2, varscan2
- TMEM215 | c.672G>C p.Q224H | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.366); catalogued as COSV61363107; called by muse, mutect2, varscan2
- TP53BP1 | c.2663C>G p.S888C | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV55495778; called by muse, mutect2, varscan2
- TRIM41 | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs201739954; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1726G>C p.E576Q | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.171); catalogued as COSV61453846; called by muse, mutect2, varscan2
- TRPM8 | c.1052C>G p.S351C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV61220329; called by muse, mutect2, varscan2
- TSR3 | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs771340303, COSV50103484; called by muse, mutect2, varscan2
- TXK | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV51912108; called by muse, varscan2
- TXK | c.1388G>T p.G463V | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51912114, COSV51912661; called by muse, varscan2
- UACA | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59852933; called by muse, mutect2, varscan2
- UBC | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV100298900, COSV60058767; called by muse, varscan2
- UNC93A | c.1347G>T p.E449D | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV57806778; called by muse, varscan2
- USP40 | c.1188G>C p.Q396H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); catalogued as COSV99296127; called by muse, mutect2
- WDR55 | c.512T>A p.I171N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64225526; called by muse, mutect2, varscan2
- WDR62 | c.273T>G p.C91W | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54331417; called by muse, mutect2, varscan2
- XPNPEP2 | c.452G>C p.G151A | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64367746; called by muse, mutect2
- XRN1 | c.3458C>T p.T1153I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.211); catalogued as COSV53807321; called by muse, mutect2, varscan2
- ZFP37 | c.1555T>G p.C519G | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65285745; called by muse, mutect2, varscan2
- ZNF141 | c.990G>C p.K330N | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.29); catalogued as COSV53656487; called by muse, mutect2, varscan2
- ZNF398 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV60064389; called by muse, mutect2, varscan2
- ZNF425 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.378); catalogued as COSV65200500, COSV65200590; called by muse, mutect2
- ZNF555 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.574); catalogued as rs141088568; called by muse, mutect2, varscan2
- ZNF600 | c.685C>G p.Q229E | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV57741210; called by muse, mutect2, varscan2
- ZNF624 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV60938628; called by muse, mutect2, varscan2
- ZNF711 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.831); catalogued as COSV52151032; called by muse, mutect2, varscan2
- ZNF804A | c.3337G>A p.A1113T | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56433821; called by muse, mutect2, varscan2
- ARHGAP35 | c.2259del p.V754Ffs*2 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- ARHGAP6 | c.2915C>T p.T972M (on ENST00000337414 / NM_013427.3; = p.T769M on NM_013423.3) | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- GCFC2 | c.1091_1092dup p.R365Nfs*7 | Frame Shift Ins (INS) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- KMT2A | c.6350_6351del p.I2117Kfs*57 | Frame Shift Del (DEL) | VAF 28/134 reads (21%) | called by pindel, varscan2
- SIPA1L3 | c.4895_4905delinsCCGCG p.R1632_D1635delinsPA | In Frame Del (DEL) | VAF 30/234 reads (13%) | called by pindel, varscan2*
- SLX4IP | c.132_134del p.L45del | In Frame Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, pindel, varscan2
- ALMS1 | c.9309C>T p.T3103= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs1319009177, COSV52501540; called by muse, mutect2, varscan2
- ALPK1 | c.2814C>T p.S938= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV51581268; called by muse, mutect2, varscan2
- APOB | c.3126G>A p.A1042= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs547789079, COSV51921607; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARID3B | c.1584C>T p.L528= (on ENST00000622429 / NM_001307939.1; = p.L527= on NM_006465.4) | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs768111580, COSV100654582; called by muse, mutect2, varscan2
- CAMK2A | c.1416G>A p.A472= (on ENST00000348628 / NM_171825.2; = p.A483= on NM_015981.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs759852005, COSV62244851; called by muse, mutect2, varscan2
- CCSER2 | c.1974G>C p.V658= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV56500908; called by muse, mutect2, varscan2
- COL6A1 | c.2847C>T p.G949= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs575066401, COSV62611230; called by muse, mutect2, varscan2
- DISP3 | c.57G>A p.E19= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV53819398; called by muse, mutect2, varscan2
- DNAH1 | c.3168C>T p.N1056= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1323452473, COSV70225919; called by muse, mutect2, varscan2
- EML1 | c.1803C>T p.V601= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs1259951857, COSV51740829; called by muse, mutect2, varscan2
- FAM71B | c.300C>G p.V100= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV57227330, COSV57230136; called by muse, mutect2, varscan2
- FCER1A | c.243G>A p.V81= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV63666372; called by muse, mutect2, varscan2
- FCRL2 | c.972G>A p.L324= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV63832395, COSV63832420; called by muse, mutect2, varscan2
- FKRP | c.1371C>T p.F457= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs1270459605, COSV59358424; called by muse, mutect2
- FMN2 | c.3408C>T p.P1136= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs772212660, COSV100146541, COSV60432255; called by muse, varscan2
- FRY | c.4203G>C p.L1401= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV66564439, COSV66570867; called by muse, mutect2, varscan2
- GALNT8 | c.1143T>C p.Y381= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV52894262; called by muse, mutect2, varscan2
- GALP | c.39C>T p.V13= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV61999098; called by mutect2, varscan2
- GTF3A | c.882C>T p.L294= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs766647703, COSV63528445; called by muse, mutect2, varscan2
- HMCN1 | c.7821C>A p.I2607= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as COSV54873516; called by muse, mutect2, varscan2
- HMCN1 | c.11904C>T p.V3968= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as rs754067906, COSV54873530; called by muse, mutect2, varscan2
- HS3ST5 | c.39C>T p.L13= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as COSV100450524, COSV57133833; called by muse, mutect2, varscan2
- IGLV1-47 | c.63T>G p.S21= | Silent (SNP) | VAF 36/150 reads (24%) | called by muse, mutect2, varscan2
- KCTD14 | c.366G>A p.L122= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs758460279, COSV100779957, COSV62000982; called by muse, mutect2, varscan2
- LONP1 | c.2865G>A p.L955= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as COSV56797526; called by muse, mutect2, varscan2
- LRP1B | c.3645G>A p.V1215= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs774464609, COSV67182538; called by muse, mutect2, varscan2
- LRRC52 | c.186G>A p.E62= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV54231119; called by muse, mutect2, varscan2
- MUC16 | c.33673C>T p.L11225= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs1250735644, COSV67441599; called by muse, mutect2, varscan2
- MYH9 | c.3063C>T p.L1021= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV53381563; called by muse, mutect2, varscan2
- OPALIN | c.63G>A p.G21= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV64520262; called by muse, mutect2, varscan2
- PCDHB1 | c.1404G>A p.A468= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as rs782722192, COSV60629315; called by muse, mutect2
- PCDHB12 | c.1857G>A p.A619= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs1187318616, COSV99507047; called by muse, mutect2, varscan2
- PCDHGA5 | c.1938C>T p.V646= | Silent (SNP) | VAF 41/201 reads (20%) | catalogued as rs1426955979, COSV53893062; called by muse, mutect2, varscan2
- PIWIL3 | c.2286G>A p.K762= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV59993491, COSV59994022; called by muse, mutect2, varscan2
- PLS1 | c.1206G>A p.R402= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV61832548; called by muse, mutect2, varscan2
- PTCHD1 | c.225G>A p.P75= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV65058658; called by muse, mutect2, varscan2
- PTGES2 | c.1029G>A p.V343= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99476306; called by muse, mutect2
- RPS19BP1 | c.291G>A p.Q97= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV58180034; called by muse, mutect2, varscan2
- SCG2 | c.1791C>A p.L597= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV59538863, COSV59538870; called by muse, mutect2, varscan2
- SEMA3C | c.21C>T p.C7= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs771788390, COSV54840647; called by muse, mutect2, varscan2
- SHANK3 | c.1644C>G p.S548= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV99436634; called by muse, mutect2, varscan2
- SMAD9 | c.321G>A p.L107= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV63203865; called by muse, mutect2, varscan2
- SPCS3 | c.66C>T p.L22= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs762021786, COSV72418982; called by muse, mutect2
- SPTLC3 | c.741C>G p.L247= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV65463394; called by muse, mutect2, varscan2
- TMEM198 | c.1050G>A p.L350= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV54712073; called by muse, mutect2, varscan2
- TSSK1B | c.768C>T p.D256= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs752300335, COSV66814732; called by mutect2, varscan2
- TTN | c.17607G>A p.T5869= (on ENST00000591111; = p.T4942= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as rs778145097, COSV100621706, COSV59865395; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBE4B | c.2229C>T p.G743= (on ENST00000343090 / NM_001105562.3; = p.G614= on NM_006048.5) | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs371708780; called by muse, mutect2, varscan2
- VPS13D | c.3687C>T p.N1229= | Silent (SNP) | VAF 16/172 reads (9%) | catalogued as rs757431493, COSV50621095; called by muse, mutect2
- ZSWIM5 | c.1056C>T p.G352= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs375655404; called by muse, mutect2, varscan2
- DNMT3A | c.640-1416G>A | Intron (SNP) | VAF 5/41 reads (12%) | catalogued as rs139790831; called by mutect2, varscan2
- MIR1-1 | n.38C>A | RNA (SNP) | VAF 83/289 reads (29%) | called by muse, mutect2, varscan2
- PTK2 | c.2030+2682C>T | Intron (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100569919; called by muse, mutect2, varscan2
- SSPOP | n.12044G>A | RNA (SNP) | VAF 3/18 reads (17%) | catalogued as rs1477265201, COSV65127081; called by muse, mutect2
